Somatic mutation profile of tumor specimen MP2PRT-PATYTP-TMP1-A (aliquot MP2PRT-PATYTP-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATYTP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,876 days).
Specimen MP2PRT-PATYTP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b75b582-def1-4de7-a863-86cd945208a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATYTP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATYTP-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c263c93d-d14f-4219-be41-b5ccff05b023

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 17, Silent 10, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.7645C>T p.R2549C (on ENST00000560601 / NM_001369268.1; = p.R2412C on NM_001135.3) | Missense Mutation (SNP) | VAF 131/376 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs571382991, COSV61358532; called by muse, mutect2, varscan2
- ACSS3 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 144/470 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs754483699, COSV99699330; called by muse, mutect2, varscan2
- ARHGEF15 | c.2246C>A p.P749Q | Missense Mutation (SNP) | VAF 170/486 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV62726532; called by muse, mutect2, varscan2
- DCC | c.2507C>A p.S836* | Nonsense Mutation (SNP) | VAF 104/393 reads (26%) | catalogued as COSV59095748; called by muse, mutect2, varscan2
- GAS2L3 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 114/384 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142735570, COSV99903031; called by muse, mutect2, varscan2
- OR2L5 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 95/311 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs780535850, COSV62365125; called by muse, mutect2, varscan2
- PXDN | c.3385C>T p.R1129C | Missense Mutation (SNP) | VAF 267/781 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs375850501; called by muse, mutect2, varscan2
- SMOC1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 175/533 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs749505789, COSV62760239; called by muse, mutect2, varscan2
- SORCS3 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 27/927 reads (3%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV63804043; called by muse, mutect2
- TCF7L2 | c.1259G>A p.R420Q (on ENST00000355995 / NM_001367943.1; = p.R397Q on NM_030756.5) | Missense Mutation (SNP) | VAF 122/364 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs867720073, COSV53338337; called by muse, mutect2, varscan2
- USP7 | c.3016C>T p.P1006S | Missense Mutation (SNP) | VAF 120/368 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV61216906; called by muse, mutect2, varscan2
- WASF3 | c.1427C>T p.T476M | Missense Mutation (SNP) | VAF 203/615 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775028272, COSV58970141; called by muse, mutect2, varscan2
- ZNF687 | c.2188C>T p.R730* | Nonsense Mutation (SNP) | VAF 219/647 reads (34%) | catalogued as rs1218706178, COSV55018053; called by muse, mutect2, varscan2
- C4orf54 | c.2930G>A p.G977E | Missense Mutation (SNP) | VAF 18/530 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2
- G0S2 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 43/1099 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2
- MAP4K1 | c.2333C>T p.S778L | Missense Mutation (SNP) | VAF 128/396 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRKACG | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 169/501 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SPTBN1 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.099); called by mutect2, varscan2
- TXNRD3 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 343/1036 reads (33%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CPLANE2 | c.678C>T p.D226= | Silent (SNP) | VAF 311/923 reads (34%) | catalogued as rs781533397; called by muse, mutect2, varscan2
- CTAGE8 | c.2292C>T p.Y764= | Silent (SNP) | VAF 30/85 reads (35%) | called by mutect2, varscan2
- FAM189B | c.1794C>T p.A598= | Silent (SNP) | VAF 212/675 reads (31%) | catalogued as COSV59170017; called by muse, mutect2, varscan2
- FAT1 | c.7398A>T p.S2466= | Silent (SNP) | VAF 155/517 reads (30%) | catalogued as rs749480216; called by muse, mutect2, varscan2
- FAT4 | c.5671C>T p.L1891= | Silent (SNP) | VAF 99/329 reads (30%) | called by muse, mutect2, varscan2
- KCTD1 | c.516C>T p.G172= | Silent (SNP) | VAF 141/551 reads (26%) | catalogued as rs1387141308; called by muse, mutect2, varscan2
- MED24 | c.2346C>T p.V782= | Silent (SNP) | VAF 185/633 reads (29%) | called by muse, mutect2, varscan2
- MYO3A | c.3159G>A p.K1053= | Silent (SNP) | VAF 117/357 reads (33%) | catalogued as rs1442858325; called by muse, mutect2, varscan2
- SLC38A1 | c.363C>T p.L121= | Silent (SNP) | VAF 49/196 reads (25%) | catalogued as rs774782936; called by muse, mutect2, varscan2
- TTLL6 | c.1341C>T p.V447= (on ENST00000393382 / NM_001130918.3; = p.V140= on NM_173623.3) | Silent (SNP) | VAF 164/502 reads (33%) | called by muse, mutect2, varscan2
